CCDI case PBBSGI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/48044ab4-4acf-4134-b3dd-f10a46c2a7f5

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,271 days).

Biospecimens (3 samples)
- Sample 0DFJJ3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFJKF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFJMX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
